Somatic mutation profile of tumor specimen TCGA-X7-A8DJ-01A (aliquot TCGA-X7-A8DJ-01A-11D-A423-09) from TCGA case TCGA-X7-A8DJ, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 68.6 years (25,042 days).
Specimen TCGA-X7-A8DJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88a1a091-2a84-411c-a6f0-2b0c11c011f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DJ-10B (Blood Derived Normal), aliquot TCGA-X7-A8DJ-10B-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8f5779a-1911-436c-88b9-f76f18f3b9df

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 37/405 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- GRAMD1C | c.1765T>C p.F589L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1186273066, COSV63982724; called by muse, mutect2
- RBM42 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV52897602; called by muse, mutect2
- GRM7 | c.2699G>C p.S900T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by mutect2, varscan2
- NR2C2 | c.1789T>C p.*597Qext*? (on ENST00000393102; = p.*616Qext*35 on NM_003298.5) | Nonstop Mutation (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TNN | c.391T>A p.C131S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM3 | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
